Somatic mutation profile of tumor specimen C3N-00243-03 (aliquot CPT0025450009) from CPTAC case C3N-00243, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 77.9 years (28,454 days).
Specimen C3N-00243-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac40e916-1525-49a0-a08a-00d5883b73dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00243-32 (Blood Derived Normal), aliquot CPT0028430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eca56084-dac4-46fa-92e0-3d0d998e734e

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Intron 5, Nonsense Mutation 4, Frame Shift Del 4, 5'UTR 2, Splice Site 1, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.981G>C p.Q327H | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65551604; called by muse, mutect2, varscan2
- ARC | c.951C>A p.D317E | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100751732; called by muse, mutect2, varscan2
- BTRC | c.836T>G p.I279S (on ENST00000370187 / NM_033637.4; = p.I243S on NM_003939.5) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV64580916; called by muse, mutect2, varscan2
- FLYWCH1 | c.1241C>G p.A414G (on ENST00000253928 / NM_001308068.2; = p.A413G on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99559260; called by muse, mutect2, varscan2
- GRM3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 13/422 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1385120633, COSV64474356; called by muse, mutect2
- GSTM3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs199932714; called by muse, mutect2, varscan2
- IQCA1 | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1410995798, COSV54496527; called by muse, mutect2, varscan2
- PRRC2A | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1194862246; called by muse, mutect2, varscan2
- REXO4 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as rs1554781148; called by muse, mutect2, varscan2
- SEZ6L2 | c.1430C>T p.T477M (on ENST00000308713 / NM_001114099.3; = p.T407M on NM_012410.4) | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs897489712, COSV58100370; called by muse, mutect2, varscan2
- VIM | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 101/415 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.233); catalogued as rs972743635; called by muse, mutect2, varscan2
- WDR70 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99459727; called by muse, mutect2, varscan2
- XYLB | c.1465T>C p.F489L | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs1262039268; called by muse, mutect2, varscan2
- ADGRV1 | c.14552A>G p.Q4851R | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AGPS | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANKRD13B | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ATP1A4 | c.2700C>G p.Y900* | Nonsense Mutation (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- ATP2C1 | c.1708A>G p.T570A | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- BCKDK | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 18/534 reads (3%) | called by muse, mutect2
- CASQ1 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COL6A5 | c.2993-2A>T p.X998_splice | Splice Site (SNP) | VAF 51/195 reads (26%) | called by muse, mutect2, varscan2
- CUBN | c.5768T>G p.I1923S | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- DHX38 | c.453A>C p.E151D | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- EML1 | c.2285A>T p.K762I | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ENPP3 | c.2257T>G p.Y753D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FAM189A2 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- FBXL15 | c.807_811del p.V271Hfs*45 | Frame Shift Del (DEL) | VAF 122/495 reads (25%) | called by mutect2, pindel, varscan2
- FTO | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- INPP4A | c.2401G>T p.V801L (on ENST00000074304 / NM_001134224.1; = p.V762L on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KDM5A | c.23dup p.Y9Lfs*15 | Frame Shift Ins (INS) | VAF 36/212 reads (17%) | called by mutect2, pindel, varscan2
- LCMT2 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LPA | c.5324G>T p.G1775V | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MALRD1 | c.4646del p.S1549Tfs*2 | Frame Shift Del (DEL) | VAF 47/176 reads (27%) | called by mutect2, pindel, varscan2
- MYOM1 | c.324T>G p.Y108* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- NCAM1 | c.2003A>C p.H668P (on ENST00000316851 / NM_181351.5; = p.H658P on NM_000615.7) | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- NDUFS3 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 126/463 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NRG2 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, varscan2
- PLCH1 | c.1578A>C p.L526F (on ENST00000340059 / NM_001130960.2; = p.L538F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.152); called by muse, mutect2
- PLSCR1 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- RIPK4 | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- RPP25L | c.468A>C p.R156S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); called by muse, varscan2
- SLC16A10 | c.997A>C p.M333L | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC35F6 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPG11 | c.3458T>A p.L1153* | Nonsense Mutation (SNP) | VAF 68/207 reads (33%) | called by muse, mutect2, varscan2
- SUGP2 | c.303C>A p.S101R | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TADA2A | c.150del p.F50Lfs*14 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- TIA1 | c.773C>T p.S258F (on ENST00000433529 / NM_001351511.1; = p.S247F on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TPP1 | c.17+4_17+15del | Splice Region (DEL) | VAF 105/679 reads (15%) | called by mutect2, pindel, varscan2
- TRAK2 | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- UIMC1 | c.432del p.E145Rfs*68 | Frame Shift Del (DEL) | VAF 64/232 reads (28%) | called by mutect2, pindel, varscan2
- VPS54 | c.1435G>T p.V479F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ZBTB17 | c.2140C>T p.H714Y | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZBTB25 | c.518_535del p.A173_D178del | In Frame Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- BACH2 | c.924G>A p.E308= | Silent (SNP) | VAF 75/299 reads (25%) | called by muse, mutect2, varscan2
- DNAH14 | c.7854C>G p.L2618= (on ENST00000445597; = p.L3421= on NM_001367479.1) | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV100586891; called by muse, mutect2, varscan2
- JPH1 | c.483C>T p.T161= | Silent (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- KAZN | c.1542C>A p.G514= | Silent (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- KLK12 | c.483C>T p.C161= | Silent (SNP) | VAF 179/670 reads (27%) | catalogued as COSV51576023, COSV51578354; called by muse, mutect2, varscan2
- NSD2 | c.1395A>G p.Q465= | Silent (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- SESN3 | c.357T>C p.H119= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- SLC22A7 | c.438T>C p.A146= (on ENST00000372585 / NM_153320.2; = p.A144= on NM_006672.3) | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as rs933515639; called by muse, mutect2, varscan2
- SPHKAP | c.1860C>G p.L620= | Silent (SNP) | VAF 68/269 reads (25%) | called by muse, mutect2, varscan2
- TCP11L1 | c.1494C>T p.Y498= | Silent (SNP) | VAF 79/300 reads (26%) | catalogued as rs376486351; called by muse, mutect2, varscan2
- TIGD3 | c.1110G>A p.T370= | Silent (SNP) | VAF 125/496 reads (25%) | catalogued as COSV52891074; called by muse, mutect2, varscan2
- XRN1 | c.4087C>T p.L1363= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as COSV99378050; called by muse, mutect2, varscan2
- A2M | c.*61C>T | 3'UTR (SNP) | VAF 11/129 reads (9%) | catalogued as rs758405590; called by muse, mutect2
- C16orf97 | n.304C>G | RNA (SNP) | VAF 90/198 reads (45%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178056075 C>G | 3'Flank (SNP) | VAF 107/461 reads (23%) | called by muse, mutect2, varscan2
- GRM7 | c.-112C>T | 5'UTR (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- LY6G6E | c.178+19G>C | Intron (SNP) | VAF 57/239 reads (24%) | called by muse, mutect2, varscan2
- NIPAL3 | c.1021+1913T>G | Intron (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- PDE4D | c.456-59422A>G | Intron (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- PTRH1 | c.96+95C>T | Intron (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- SDC4 | c.-1C>T | 5'UTR (SNP) | VAF 20/308 reads (6%) | catalogued as rs1397850339, COSV65595047, COSV65595807; called by muse, mutect2
- TNRC18 | c.187+359G>A | Intron (SNP) | VAF 11/190 reads (6%) | called by muse, mutect2
